Gene-level copy-number profile of tumor specimen HTMCP-03-06-02058-01B from CGCI case HTMCP-03-06-02058, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 33.5 years (12,229 days).
Specimen HTMCP-03-06-02058-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a49caa67-2b65-4edb-9ef9-717a444e5851.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02058-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,248 have no estimate.
https://portal.gdc.cancer.gov/files/146830e8-fedc-459b-b5d2-41b97a2df5a6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 13,866; copy number 2: 30,997; copy number 3: 12,043; copy number 4: 1,220; copy number 5: 183; copy number 6: 21; copy number 7: 1; copy number 9: 1; copy number 12: 6.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–143,825,837, 21 genes: AC242852.1, AC242852.2, AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1.
- chr1:143,874,793–144,068,350, 5 genes (within-gene range 0–1): FCGR1CP, H2BP2, H3-2, FAM72C, SRGAP2D.
- chr1:248,573,801–248,645,278, 6 genes: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35.
- chr6:168,441,151–168,673,445, 1 gene: SMOC2.
- chr13:112,313,467–112,331,225, 2 genes: LINC01043, LINC01044.
- chr14:23,969,874–24,051,377, 2 genes (within-gene range 0–1): DHRS4L2, AL136419.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 212 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:144,085,628–144,401,355, 9 genes, copy number 6: IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4.
- chr1:144,965,025–145,242,124, 7 genes, copy number 9–12: AC242498.1, FAM72D, LINC01145, RNU1-153P, AC241585.2, AC241585.1, PPIAL4D.
- chr1:145,866,560–146,036,746, 14 genes, copy number 5: ANKRD35, ITGA10, AC243547.1, PEX11B, RBM8A, GNRHR2, LIX1L-AS1, AC243547.3, LIX1L, ANKRD34A, AC243547.2, POLR3GL, TXNIP, HJV.
- chr3:138,889,255–138,889,957, 1 gene, copy number 7: ATP5MC1P3.
- chr3:170,222,424–170,418,615, 5 genes, copy number 5: PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2.
- chr3:177,294,442–177,323,418, 2 genes, copy number 5: LINC00501, ASS1P7.
- chr5:36,861,736–45,895,970, 137 genes, copy number 5–6 (broad region; genes not listed).
- chr7:66,025,126–66,165,011, 6 genes, copy number 5: AC068533.2, AC068533.1, ASL, AC068533.4, CRCP, AC068533.3.
- chr7:104,940,943–105,014,321, 3 genes, copy number 5 (within-gene range 3–5): AC007384.1, LINC01004, KMT2E-AS1.
- chr7:149,053,961–149,191,223, 6 genes, copy number 5: COX6B1P1, ZNF786, ZNF425, RN7SL521P, ZNF398, AC004890.1.
- chr8:97,624,203–97,772,425, 3 genes, copy number 5: AP002982.1, MTDH, Y_RNA.
- chr8:123,416,726–123,470,028, 1 gene, copy number 6 (within-gene range 3–6): NTAQ1.
- chr9:19,108,375–19,373,545, 4 genes, copy number 5 (within-gene range 3–5): PLIN2, AL161909.1, DENND4C, AL161909.2.
- chr9:125,146,573–125,189,939, 1 gene, copy number 5 (within-gene range 2–5): PPP6C.
- chr9:125,194,649–125,257,071, 4 genes, copy number 5: RPSAP76, RABEPK, HSPA5, AL354710.2.
- chr11:62,761,565–62,806,302, 9 genes, copy number 5: POLR2G, AP001160.2, TAF6L, TMEM223, AP001160.3, TMEM179B, MIR6748, NXF1, MIR6514.

Autosomal genes at a single copy (total copy number 1): 11,617. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
